Somatic mutation profile of tumor specimen TCGA-14-1827-01A (aliquot TCGA-14-1827-01A-01W-0643-08) from TCGA case TCGA-14-1827, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 51.5 years (18,828 days).
Specimen TCGA-14-1827-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d81b70a6-a103-4301-95f2-423be83b54e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-14-1827-10A (Blood Derived Normal), aliquot TCGA-14-1827-10A-01W-0644-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf7c0694-20b7-473d-b28f-0940878a3af7

The open-access MAF lists 48 somatic variants for this specimen: 32 protein-altering or splice-affecting, 13 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 13, Frame Shift Del 3, Splice Site 2, Nonsense Mutation 2, Frame Shift Ins 2, Intron 1, 5'UTR 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC9 | c.3728C>T p.S1243L | Missense Mutation (SNP) | VAF 56/163 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs751402564, COSV53964356; called by muse, mutect2, varscan2
- ACER2 | c.268C>A p.Q90K | Missense Mutation (SNP) | VAF 9/256 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100575893; called by muse, mutect2
- AP002748.5 | c.405G>T p.E135D | Missense Mutation (SNP) | VAF 17/168 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.085); catalogued as COSV100568228; called by muse, mutect2, varscan2
- APBB1 | c.1447C>T p.R483C | Missense Mutation (SNP) | VAF 96/295 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs184224900, COSV54975089; called by muse, mutect2, varscan2
- CCDC66 | c.1319+3_1319+6del p.X440_splice (on ENST00000394672 / NM_001353147.1; = p.X406_splice on NM_001012506.5 and 6 other RefSeq transcripts) | Splice Site (DEL) | VAF 38/120 reads (32%) | catalogued as rs761792404; called by pindel, varscan2
- CHAT | c.1441dup p.R481Pfs*30 | Frame Shift Ins (INS) | VAF 4/33 reads (12%) | catalogued as rs773268576; called by pindel, varscan2
- COL3A1 | c.160G>A p.V54I | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as COSV104394937, COSV58582232; called by muse, mutect2
- DIAPH3 | c.1955T>A p.L652* (on ENST00000400324 / NM_001042517.2; = p.L389* on NM_030932.3) | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | catalogued as COSV99934543, COSV99934655; called by muse, mutect2, varscan2
- EGFR | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 3172/3260 reads (97%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.64); catalogued as rs1229095978, COSV99295901; called by muse, mutect2, varscan2
- FRRS1 | c.556G>A p.V186I | Missense Mutation (SNP) | VAF 73/680 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as rs143942842; called by muse, mutect2, varscan2
- FSIP1 | c.1537G>A p.V513I | Missense Mutation (SNP) | VAF 65/196 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as rs758206272, COSV63225603; called by muse, mutect2, varscan2
- GAP43 | c.275C>T p.P92L | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV100526037; called by muse, mutect2, varscan2
- KCNB1 | c.2009G>A p.R670Q | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.67); catalogued as rs753575587, COSV100870420, COSV100870610; ClinVar: likely benign; called by muse, mutect2, varscan2
- KCTD9 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV55340859; called by muse, mutect2, varscan2
- KIFAP3 | c.1672G>A p.G558S | Missense Mutation (SNP) | VAF 11/177 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV100847176; called by muse, mutect2
- LMAN2 | c.272C>T p.T91I | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100288525; called by muse, mutect2, varscan2
- NDN | c.718G>A p.V240I | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs549529148, COSV100086387; called by muse, mutect2, varscan2
- NNMT | c.370G>A p.G124S | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.458); catalogued as rs768961761, COSV100248957; called by muse, mutect2, varscan2
- OR2M3 | c.208G>T p.D70Y | Missense Mutation (SNP) | VAF 48/846 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV101513537; called by muse, mutect2
- SLC22A3 | c.801G>A p.W267* | Nonsense Mutation (SNP) | VAF 116/263 reads (44%) | catalogued as COSV51714849; called by muse, mutect2, varscan2
- SRPRA | c.1241G>A p.R414H | Missense Mutation (SNP) | VAF 63/184 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.629); catalogued as rs931575088, COSV99703181; called by muse, mutect2, varscan2
- STK36 | c.3347G>T p.S1116I | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV55328427, COSV99832022; called by muse, mutect2, varscan2
- TNNI1 | c.415C>T p.R139W | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1485635367, COSV100270468; called by muse, mutect2, varscan2
- TP53BP1 | c.3986G>C p.S1329T | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); catalogued as rs1443104681, COSV99781705; called by muse, mutect2, varscan2
- TULP4 | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 93/227 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100893609, COSV100893877, COSV100893888; called by muse, mutect2, varscan2
- UBE2M | c.361C>A p.P121T | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99448416; called by muse, mutect2, varscan2
- C15orf39 | c.580dup p.V194Gfs*4 | Frame Shift Ins (INS) | VAF 6/46 reads (13%) | called by mutect2, pindel, varscan2
- IREB2 | c.1023+8_1023+13del | Splice Region (DEL) | VAF 22/103 reads (21%) | called by mutect2, pindel, varscan2
- KMT2A | c.11164del p.I3722Ffs*37 | Frame Shift Del (DEL) | VAF 49/198 reads (25%) | called by mutect2, pindel, varscan2
- LRRIQ1 | c.4008-1G>A p.X1336_splice | Splice Site (SNP) | VAF 6/26 reads (23%) | called by muse, mutect2
- SERPINB3 | c.457del p.S153Vfs*10 | Frame Shift Del (DEL) | VAF 19/74 reads (26%) | called by mutect2, pindel, varscan2
- WDHD1 | c.1053del p.I353Lfs*2 | Frame Shift Del (DEL) | VAF 23/80 reads (29%) | called by mutect2, pindel, varscan2
- ANO7 | c.858C>T p.V286= (on ENST00000274979; = p.V232= on NM_001370694.2) | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as COSV99239673; called by muse, mutect2, varscan2
- DFFA | c.954T>A p.G318= | Silent (SNP) | VAF 9/60 reads (15%) | called by mutect2, varscan2
- DNAAF1 | c.1350G>A p.P450= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs148990251; ClinVar: likely benign / uncertain significance; called by muse, varscan2
- EGFR | c.267C>T p.V89= | Silent (SNP) | VAF 6292/6447 reads (98%) | catalogued as COSV99295898; called by muse, mutect2, varscan2
- IL36A | c.354C>T p.F118= | Silent (SNP) | VAF 60/163 reads (37%) | catalogued as COSV99382304; called by muse, mutect2, varscan2
- KDM4B | c.1023G>C p.V341= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV99347618; called by muse, mutect2
- OR2AG1 | c.21C>T p.T7= | Silent (SNP) | VAF 11/189 reads (6%) | catalogued as COSV100265012; called by muse, mutect2
- PIEZO2 | c.6618C>T p.F2206= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as rs755677302, COSV53287106, COSV53294280; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1512G>A p.V504= (on ENST00000352766; = p.V425= on NM_181334.5) | Silent (SNP) | VAF 290/393 reads (74%) | catalogued as rs1569186521, COSV100424749; called by muse, mutect2, varscan2
- RSPO2 | c.603G>A p.R201= | Silent (SNP) | VAF 216/779 reads (28%) | catalogued as rs759927664, COSV99410590; called by muse, mutect2, varscan2
- SYNE2 | c.10941C>T p.S3647= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as rs1189976211, COSV59972722; called by muse, mutect2, varscan2
- TRRAP | c.8565C>T p.C2855= (on ENST00000359863 / NM_001244580.1; = p.C2837= on NM_003496.3) | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as rs777625422, COSV62840828; called by muse, mutect2
- TSPAN12 | c.168T>A p.I56= | Silent (SNP) | VAF 54/391 reads (14%) | catalogued as COSV99763381; called by muse, mutect2, varscan2
- ANKRD33 | c.-370C>T | 5'UTR (SNP) | VAF 98/366 reads (27%) | catalogued as COSV100001578; called by muse, mutect2, varscan2
- CALCR | c.51+2978C>T | Intron (SNP) | VAF 86/266 reads (32%) | catalogued as rs774519762, COSV64005791, COSV64008954; called by muse, mutect2, varscan2
- LINC02694 | n.334C>T | RNA (SNP) | VAF 18/179 reads (10%) | catalogued as COSV100601959; called by muse, mutect2, varscan2
